Gene-level copy-number profile of tumor specimen TCGA-V4-A9ET-01A from TCGA case TCGA-V4-A9ET, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 57.8 years (21,113 days).
Specimen TCGA-V4-A9ET-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UVM.7af4c0c2-3fd4-4468-bb58-a8004509ec7a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-V4-A9ET-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/93048e5c-23f4-4eab-9b94-b7112396c60a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,914; copy number 2: 50,174; copy number 3: 3,200; copy number 4: 1,825; copy number 5: 707.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-V4-A9ET-01A-11D-A39V-01): tumor purity 1, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 707 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:44,809,317–52,087,613, 89 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr6:53,497,341–60,546,660, 64 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr8:83,293,925–122,428,551, 532 genes, copy number 5 (broad region; genes not listed).
- chr8:122,485,515–122,489,815, 1 gene, copy number 5: AC108136.1.
- chr8:135,234,131–139,463,016, 21 genes, copy number 5: LINC01591, AC040914.1, KHDRBS3, MAPRE1P1, RNU1-35P, LINC02055, AC103955.1, AC023781.1, RNU6-144P, ZYXP1, AC105213.1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B, COL22A1, AC027541.1, AC100807.1, AC100807.2, AC087354.1.

Autosomal genes at a single copy (total copy number 1): 1,533. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
